Somatic mutation profile of tumor specimen 0DJE3C from CCDI case PBBWKT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (65 days).
Specimen 0DJE3C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c3e4fba-11e8-41cc-8c9d-06ec2ffaea3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJE3I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0699ef9-9871-4658-afef-c774eb145cc2

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BHMT2 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 106/689 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as rs199517002; called by muse, mutect2, varscan2
- SPHKAP | c.3314C>T p.T1105M | Missense Mutation (SNP) | VAF 204/894 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs748558267, COSV60869706; called by muse, mutect2, varscan2
- MARS1 | c.201-7_201-6del | Splice Region (DEL) | VAF 94/414 reads (23%) | called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 30/306 reads (10%) | called by muse, varscan2
- SLC43A1 | c.693-23C>T | Intron (SNP) | VAF 236/476 reads (50%) | called by muse, mutect2, varscan2
